Surgical pathology report (de-identified scan), TCGA case TCGA-12-3651, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-3651-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

AP Surgical Pathology: Additional Info [REDACTED]

Surg Path

CLINICAL HISTORY:

[REDACTED] is a [REDACTED] [REDACTED] with hx of 4 seizures. Workup revealed a brain mass and he is now admitted for a craniotomy for surgical resection.

[REDACTED] MRI [REDACTED]: Interval enlargement of peripherally enhancing right temporal-occipital mass which measures approximately 7.3 x 4.0 cm. The mass extends medially along the splenium of the corpus callosum. Evidence of a right parietal burr hole with extension of enhancement laterally to toward the burrhole.

GROSS EXAMINATION:

A. "Brain tissue (Afl)", received fresh for frozen section is a 6.5 x 5.2 x up to 3.1 cm fragment of pink-tan soft tissue. Representative section is frozen as Afl and the frozen section remnant is submitted in block A1. Additional representative sections are submitted in blocks A2-8, with the remainder retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": Afl- glioblastoma [REDACTED].

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by cytologic pleomorphism, mitotic figures, microvascular changes with endothelial proliferation and pseudopalisading necrosis.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV)

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (56% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - POLYSOMY (56% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (33% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (33% OF TUMOR CELLS EXHIBIT LOSS)

9p21 - INTACT (NO LOSS)

CHROMOSOME 9 CENTROMERE - INTACT (NO LOSS)

[page 2 of 3]
4 OF 4 ABNORMAL MARKERS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

FISH DATA INDICATE THAT PTEN GENE IS LOST WHILE IMMUNOHISTOCHEMISTRY INDICATES THAT PTEN PROTEIN EXPRESSION IS INTACT. THE SIGNIFICANCE OF THIS DISCREPANCY IS UNKNOWN, BUT IT MAY REPRESENT A FALSE POSITIVE BY IMMUNOHISTOCHEMISTRY.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
[REDACTED]
[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED])

LEUCOCYTE COMMON ANTIGEN (LCA): 20% OF POSITIVE CELLS.

PROLIFERATION INDEX INTERPRETATION: HIGH PROLIFERATION INDEX (20% OF TUMOR CELLS EXHIBIT STAINING).

MGMT - POSITIVE (30% OF TUMOR CELLS)

EGFR wt - POSITIVE (2+ IN 90% OF TUMOR CELLS)

EGFR vIII - NEGATIVE (0% OF TUMOR CELLS)

PTEN - INTACT (2-3+ IN 90% OF TUMOR CELLS)

S6 - POSITIVE (2+ IN 50% OF TUMOR CELLS)

AKT - POSITIVE (2+ IN 40% OF TUMOR CELLS)

MAPK - POSITIVE (3+ IN 10% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 3:

MGMT PROMOTER METHYLATION REAL TIME PCR ANALYSIS

Received [REDACTED] from [REDACTED] is a copy of an MGMT Promoter Methylation Assay, obtained at the request of [REDACTED], on paraffin block [REDACTED]. The complete report from [REDACTED] is on file in the Image Cytometry Laboratory.

INTERPRETATION:

MGMT PROMOTER METHYLATION IDENTIFIED (METHYLATION INDEX = 449)

[page 3 of 3]
Comment: The specimen is considered negative for MGMT promoter methylation when Methylation Index (MI) is less than 4. MI between 4 and 16 is considered as low level of methylation and should be interpreted with caution since the significance of low level methylation in gliomas is not well understood. MI greater than 16 is considered as methylated.

[REDACTED]

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

Electronically signed: [REDACTED]

Performed by: [REDACTED]

Ordering MD: [REDACTED]

Source: NCI Genomic Data Commons file c0991cc0-578b-4036-a6b9-7d8853c1ded4 (TCGA-12-3651.86B63612-FC00-4710-BBB0-BAB9E15F290C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).